Somatic mutation profile of tumor specimen TARGET-20-PARANT-09A (aliquot TARGET-20-PARANT-09A-03D) from TARGET case TARGET-20-PARANT, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.5 years (6,397 days).
Specimen TARGET-20-PARANT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8afc571-0e08-4925-ac81-7f3371907ce6.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARANT-14A (Bone Marrow Normal), aliquot TARGET-20-PARANT-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03f8b4bd-d6ae-4c64-9b8a-6969ba587c69

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Frame Shift Ins 3, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 31/139 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CBFB | c.259_260insGAGATTCCT p.D87delinsGDSY | In Frame Ins (INS) | VAF 51/186 reads (27%) | catalogued as COSV52001569; called by mutect2, pindel, varscan2
- ETV6 | c.306_307insAACCT p.R103Nfs*21 | Frame Shift Ins (INS) | VAF 19/143 reads (13%) | catalogued as COSV67154527; called by mutect2, pindel, varscan2
- RELN | c.8716T>C p.W2906R | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as rs747453309, COSV59033833; called by muse, mutect2, varscan2
- BCORL1 | c.3509dup p.E1172Rfs*44 | Frame Shift Ins (INS) | VAF 29/70 reads (41%) | called by mutect2, pindel, varscan2
- NF1 | c.5392_5393insGGGA p.Q1798Rfs*22 (on ENST00000358273 / NM_001042492.3; = p.Q1777Rfs*22 on NM_000267.3) | Frame Shift Ins (INS) | VAF 20/248 reads (8%) | called by mutect2, pindel
- PCLO | c.1702C>A p.Q568K | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.006); called by muse, mutect2
